Gene-level copy-number profile of tumor specimen C3N-02324-03 from CPTAC case C3N-02324, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 38.6 years (14,084 days).
Specimen C3N-02324-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Trunk; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 6c04e519-3852-49d4-a651-6718b40482a4.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-02324-71 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,772 have no estimate.
https://portal.gdc.cancer.gov/files/6d4ee520-ca2c-4dd9-97ea-260492b27c77

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 482; copy number 1: 2,135; copy number 2: 16,894; copy number 3: 21,023; copy number 4: 10,217; copy number 5: 4,784; copy number 6: 3,053; copy number 7: 177; copy number 8: 45; copy number 9: 41.

Homozygous deletions (total copy number 0; autosomes only): 20 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:14,921,013–15,146,401, 1 gene (within-gene range 0–2): CLCN3P1.
- chr9:14,993,312–15,307,360, 4 genes: AL592293.1, PSIP1P1, RNU6-559P, TTC39B.
- chr9:21,966,929–23,438,700, 14 genes (within-gene range 0–7): CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1.
- chr13:57,204,379–57,204,799, 1 gene: MTCO2P3.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 263 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:93,262,186–93,346,025, 1 gene, copy number 7 (within-gene range 2–7): CCDC18-AS1.
- chr1:93,345,907–93,554,661, 5 genes, copy number 7: DR1, AL137159.1, Y_RNA, FNBP1L, RNA5SP53.
- chr1:119,648,411–120,355,148, 15 genes, copy number 7: PHGDH, HMGCS2, REG4, NBPF7, PFN1P9, NOTCH2P1, ADAM30, NOTCH2, AC245008.1, RNU6-465P, SEC22B, AC244669.2, 7SK, AC244669.1, U1.
- chr1:217,426,992–221,554,314, 69 genes, copy number 7 (broad region; genes not listed).
- chr1:223,951,394–225,399,292, 27 genes, copy number 9 (within-gene range 4–9): GTF2IP20, RNU6-1319P, AC138393.1, AC138393.3, AC138393.2, RN7SKP49, FBXO28, AC092809.3, DEGS1, SNORA72, AC092809.2, AC092809.4, NVL, MIR320B2, AC092809.1, RNU6-1008P, CNIH4, WDR26, MIR4742, CNIH3, AKR1B1P1, CNIH3-AS2, DNAJB6P6, AL596330.1, CNIH3-AS1, LINC02813, DNAH14.
- chr1:234,757,619–235,328,219, 16 genes, copy number 8 (within-gene range 4–8): PP2672, AL391832.4, RNY4P16, RN7SL668P, AL391832.1, AL391832.2, AL391832.3, LINC01348, AL732292.1, AL732292.2, TOMM20, SNORA14B, RBM34, ARID4B, MIR4753, RPL23AP23.
- chr1:248,573,801–248,645,278, 6 genes, copy number 7: OR2T34, OR2T10, Y_RNA, AC098483.2, OR2T11, OR2T35.
- chr2:169,064,789–169,362,534, 4 genes, copy number 9: DHRS9, AC007556.1, UBE2V1P6, LRP2.
- chr2:169,694,454–170,967,130, 26 genes, copy number 7–8: PHOSPHO2, KLHL23, AC009967.1, PTCHD3P2, CYB5AP2, SSB, METTL5, UBR3, NSA2P5, RNU6-1006P, MYO3B, MYO3B-AS1, HMGB1P4, AC007277.1, AC007277.2, AC007405.1, LINC01124, SP5, EIF2S2P4, AC007405.3, Y_RNA, ERICH2, GAD1, AC007405.2, AC007405.4, GORASP2.
- chr2:180,473,137–180,692,454, 2 genes, copy number 9 (within-gene range 5–9): AC012669.1, AC009478.1.
- chr2:181,086,076–182,131,398, 15 genes, copy number 7–9 (within-gene range 5–9): LINC01934, MIR4437, AC020595.1, ITGA4, CERKL, NEUROD1, AC013733.2, AC013733.1, SAP18P2, RNU6ATAC19P, AC009962.1, ITPRID2, PPP1R1C, KRT18P29, RNA5SP113.
- chr3:189,956,728–190,122,437, 1 gene, copy number 7 (within-gene range 4–7): P3H2.
- chr3:190,120,964–191,265,615, 16 genes, copy number 7–9: P3H2-AS1, RNU6-1109P, NMNAT1P3, CLDN1, CLDN16, TMEM207, IL1RAP, GCNT1P3, RN7SKP296, AC108747.1, LINC02013, CCT6P4, AC092952.1, GMNC, OSTN, OSTN-AS1.
- chr5:37,812,677–37,840,041, 1 gene, copy number 8: GDNF.
- chr9:21,106,543–22,029,594, 43 genes, copy number 7 (within-gene range 0–7): IFNWP4, AL390882.1, IFNW1, Y_RNA, IFNA21, IFNWP15, IFNA4, IFNWP9, IFNA7, IFNA10, IFNWP18, IFNA16, IFNA17, IFNWP5, IFNA14, IFNA22P, IFNA5, IFNA20P, KLHL9, IFNA6, IFNA13, IFNA2, AL353732.1, IFNA11P, IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3.
- chr9:60,914,407–61,662,690, 16 genes, copy number 8: SPATA31A5, AL590491.1, FAM74A6, AL590491.2, AL590491.3, SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P, AL935212.3, FAM242D, Y_RNA, AL935212.1.

Autosomal genes at a single copy (total copy number 1): 732. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
